TCGA case TCGA-MA-AA3Y — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f261704-d600-4226-90d5-d51ba416b55c

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 48.7 years (17,795 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 542 days (1.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 29; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (8 entries)
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 20 (preoperative): Days to imaging: 20 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 22 (preoperative): ECOG performance status: 1.
- Day 542 (postoperative): Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 156 cm; BMI: 26.7.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MA-AA3Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-MA-AA3Y-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MA-AA3Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MA-AA3Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Pregnancies count miscarriage: 1; Total pregnancy count: 1; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: Post operative; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 542 days; disease-specific survival: no event (censored), 542 days; disease-free interval: no event (censored), 542 days; progression-free interval: no event (censored), 542 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MA-AA3Y-01A-11D-A386-01): tumor purity 0.47, ploidy 2.05, whole-genome doublings 0.
